Somatic mutation profile of tumor specimen C3N-02150-04 (aliquot CPT0118700006) from CPTAC case C3N-02150, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 49.4 years (18,050 days).
Specimen C3N-02150-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57b5fba1-a101-44a6-99d1-93f50353bafa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02150-31 (Blood Derived Normal), aliquot CPT0119930002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af098cb9-b901-4f06-ba8e-3f20a95ffec3

The open-access MAF lists 464 somatic variants for this specimen: 313 protein-altering or splice-affecting, 102 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 259, Silent 102, Nonsense Mutation 31, Intron 16, RNA 11, Splice Site 9, Frame Shift Del 7, 3'UTR 7, 5'Flank 7, Splice Region 6, 5'UTR 5, 3'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.1466A>G p.Y489C | Missense Mutation (SNP) | VAF 65/244 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs137854557, CM1111787, CS992455, COSV62194445; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 25/217 reads (12%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABCC5 | c.4250A>G p.N1417S | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.373); catalogued as rs1023050937; called by muse, mutect2, varscan2
- ACACB | c.554G>T p.R185L | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.051); catalogued as rs147024369; called by muse, mutect2
- ADAMTS12 | c.3086C>A p.P1029H | Missense Mutation (SNP) | VAF 140/468 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV61269777; called by muse, mutect2, varscan2
- AGXT | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1171762321, COSV100280329; called by muse, mutect2, varscan2
- BCOR | c.2743G>C p.G915R | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100653121; called by muse, mutect2
- BMERB1 | c.264G>T p.M88I | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.088); catalogued as COSV100252855, COSV55506759; called by muse, mutect2, varscan2
- BMERB1 | c.265G>T p.D89Y | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as COSV55513648; called by muse, mutect2, varscan2
- BRINP1 | c.448C>A p.L150I | Missense Mutation (SNP) | VAF 37/253 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV56306934; called by muse, mutect2, varscan2
- CCDC39 | c.884C>G p.T295R | Missense Mutation (SNP) | VAF 36/293 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.085); catalogued as COSV56482150, COSV56483486; called by muse, mutect2, varscan2
- CDH12 | c.990C>G p.I330M | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV104428536; called by muse, mutect2, varscan2
- CFAP54 | c.6749G>T p.S2250I | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV61573313; called by muse, mutect2, varscan2
- CHFR | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99904874; called by muse, mutect2
- CNTN4 | c.1708C>A p.H570N | Missense Mutation (SNP) | VAF 77/554 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61877175; called by muse, mutect2, varscan2
- COL6A5 | c.229G>T p.E77* | Nonsense Mutation (SNP) | VAF 14/144 reads (10%) | catalogued as COSV55196656; called by muse, mutect2, varscan2
- CRACD | c.2378A>G p.K793R | Missense Mutation (SNP) | VAF 66/530 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1273510704; called by muse, mutect2, varscan2
- CSMD1 | c.5791C>G p.R1931G (on ENST00000520002; = p.R1930G on NM_033225.6) | Missense Mutation (SNP) | VAF 37/327 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59378890; called by muse, mutect2, varscan2
- CTNNA2 | c.2074C>T p.Q692* | Nonsense Mutation (SNP) | VAF 16/218 reads (7%) | catalogued as COSV100559527, COSV58160643; called by muse, mutect2
- DENND4C | c.2824A>C p.T942P | Missense Mutation (SNP) | VAF 22/217 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as COSV66823604; called by muse, mutect2, varscan2
- DLGAP2 | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 37/282 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.988); catalogued as rs1479349079, COSV70097590; called by muse, mutect2, varscan2
- DMBT1 | c.167T>G p.L56R | Missense Mutation (SNP) | VAF 26/306 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.514); catalogued as COSV57541928; called by muse, mutect2
- DOCK2 | c.2783G>A p.R928Q | Missense Mutation (SNP) | VAF 26/205 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.098); catalogued as rs754028409, COSV56961008; called by muse, mutect2, varscan2
- DPT | c.449C>A p.P150Q | Missense Mutation (SNP) | VAF 29/366 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV63190028; called by muse, mutect2
- DST | c.9572C>T p.A3191V | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.005); catalogued as rs1309531270; called by muse, mutect2
- EEF1E1 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.572); catalogued as COSV101121268; called by muse, mutect2
- EFHB | c.2390G>T p.W797L | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as COSV99859461, COSV99860046; called by muse, mutect2
- EPPK1 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as rs187605642; called by muse, mutect2, varscan2
- EYA1 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 35/288 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as COSV58169370; called by muse, mutect2, varscan2
- FCN2 | c.331C>T p.R111* | Nonsense Mutation (SNP) | VAF 67/398 reads (17%) | catalogued as rs376463516; called by muse, mutect2, varscan2
- FJX1 | c.991G>A p.G331S | Missense Mutation (SNP) | VAF 64/492 reads (13%) | SIFT tolerated (0.87); PolyPhen benign (0.007); catalogued as rs1183052315; called by muse, mutect2, varscan2
- FOXB2 | c.1082C>A p.A361D | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs185343383; called by muse, mutect2, varscan2
- FSIP2 | c.14792C>A p.A4931E | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.773); catalogued as rs1284330324; called by muse, mutect2
- GAD2 | c.183C>A p.S61R | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs567040121; called by muse, mutect2, varscan2
- GATA3 | c.403C>A p.P135T | Missense Mutation (SNP) | VAF 30/297 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV60521064; called by muse, mutect2
- GIMAP7 | c.647G>T p.R216L | Missense Mutation (SNP) | VAF 56/327 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV57960641; called by muse, mutect2, varscan2
- GPATCH1 | c.865G>C p.G289R | Missense Mutation (SNP) | VAF 34/185 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50124476, COSV99404114; called by muse, mutect2, varscan2
- GPX5 | c.188A>T p.H63L | Missense Mutation (SNP) | VAF 37/207 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.009); catalogued as COSV69079583; called by muse, mutect2, varscan2
- HMCN1 | c.10412G>C p.R3471T | Missense Mutation (SNP) | VAF 36/507 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV54885550; called by muse, mutect2
- HMCN1 | c.11425G>C p.G3809R | Missense Mutation (SNP) | VAF 106/530 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1242678606, COSV54897447, COSV54927388; called by muse, mutect2, varscan2
- HOXC10 | c.356G>T p.R119L | Missense Mutation (SNP) | VAF 30/264 reads (11%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.513); catalogued as rs1486294299; called by muse, mutect2, varscan2
- IGF2BP2 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as rs1050135405, COSV60483761; called by muse, varscan2
- INPP4B | c.1720+1G>C p.X574_splice | Splice Site (SNP) | VAF 14/106 reads (13%) | catalogued as COSV53752410; called by muse, varscan2
- INTS6L | c.1642A>G p.S548G | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs1165433675; called by muse, mutect2
- ITGA8 | c.2353G>A p.A785T | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV65223880; called by muse, mutect2, varscan2
- JAKMIP1 | c.190C>G p.R64G | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV51547166; called by muse, mutect2
- JPH2 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 37/212 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868619268; called by muse, mutect2, varscan2
- KEL | c.1934C>T p.A645V | Missense Mutation (SNP) | VAF 69/533 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs147851584, CM165859, COSV62335323; called by muse, mutect2, varscan2
- KLHL18 | c.1016A>G p.Y339C | Missense Mutation (SNP) | VAF 51/401 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs139680090; called by muse, mutect2, varscan2
- KLK7 | c.74-1G>A p.X25_splice | Splice Site (SNP) | VAF 32/153 reads (21%) | catalogued as COSV58344507; called by muse, mutect2, varscan2
- KRTAP10-11 | c.663C>A p.C221* | Nonsense Mutation (SNP) | VAF 54/646 reads (8%) | catalogued as rs1035288148; called by muse, mutect2
- KRTAP22-1 | c.59G>T p.C20F | Missense Mutation (SNP) | VAF 28/400 reads (7%) | PolyPhen benign (0.177); catalogued as COSV58181977; called by muse, mutect2
- LBR | c.862G>C p.D288H | Missense Mutation (SNP) | VAF 13/362 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.906); catalogued as rs1425669232; called by muse, mutect2
- LIPE | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 19/232 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs138508614; called by muse, mutect2
- LOXHD1 | c.2509C>A p.Q837K | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.969); catalogued as COSV56063005; called by muse, mutect2
- LRIT1 | c.52del p.Q18Rfs*26 | Frame Shift Del (DEL) | VAF 18/148 reads (12%) | catalogued as rs759958964; called by mutect2, pindel
- LRRC66 | c.1475G>T p.G492V | Missense Mutation (SNP) | VAF 52/315 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.725); catalogued as COSV100602851, COSV58632099; called by muse, mutect2, varscan2
- LRRC66 | c.1474G>T p.G492W | Missense Mutation (SNP) | VAF 53/313 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100602927; called by muse, mutect2, varscan2
- LRRC7 | c.4084G>A p.D1362N | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as COSV50481424; called by muse, mutect2, varscan2
- MAGEB6B | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.594); catalogued as rs753146008; called by muse, mutect2, varscan2
- MEP1A | c.1164G>T p.W388C | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57918053, COSV57921239; called by muse, mutect2, varscan2
- MTCL1 | c.4723C>T p.P1575S (on ENST00000306329 / NM_001378206.1; = p.P1256S on NM_015210.4) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.169); catalogued as rs1178074741; called by muse, mutect2, varscan2
- MYBPC1 | c.2279G>A p.G760E (on ENST00000550270 / NM_206820.2; = p.G785E on NM_002465.4) | Missense Mutation (SNP) | VAF 21/428 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62251578; called by muse, mutect2
- MYH15 | c.2674C>G p.L892V | Missense Mutation (SNP) | VAF 23/194 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV56310061; called by muse, mutect2, varscan2
- MYL2 | c.67C>A p.Q23K | Missense Mutation (SNP) | VAF 45/376 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as COSV99960891; called by muse, mutect2, varscan2
- NLRP14 | c.2095C>A p.H699N | Missense Mutation (SNP) | VAF 40/428 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as rs760003462; called by muse, mutect2
- NR1H4 | c.630C>A p.G210= (on ENST00000551379 / NM_001206993.2; = p.C196* on NM_005123.4) | Splice Region (SNP) | VAF 37/367 reads (10%) | catalogued as COSV51855860; called by muse, mutect2, varscan2
- NTSR1 | c.361C>A p.P121T | Missense Mutation (SNP) | VAF 37/399 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200124409; called by muse, mutect2
- OR2M7 | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 34/318 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100522724, COSV58740073; called by muse, mutect2, varscan2
- OR4A47 | c.569C>A p.T190N | Missense Mutation (SNP) | VAF 30/241 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV71444885; called by muse, mutect2, varscan2
- OR52K1 | c.323C>G p.S108C | Missense Mutation (SNP) | VAF 28/396 reads (7%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.998); catalogued as rs1478019515, COSV56904443; called by muse, mutect2
- OR5F1 | c.211G>T p.V71F | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.014); catalogued as COSV53547223; called by muse, mutect2, varscan2
- PABPC1 | c.1364G>T p.R455L | Missense Mutation (SNP) | VAF 26/353 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs756598175, COSV59401593; called by muse, mutect2
- PALD1 | c.1208G>C p.R403P | Missense Mutation (SNP) | VAF 43/304 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.034); catalogued as COSV54971569; called by muse, mutect2, varscan2
- PCDH11X | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.233); catalogued as COSV53453445; called by muse, mutect2, varscan2
- PCDHGB6 | c.1577G>T p.R526L | Missense Mutation (SNP) | VAF 44/337 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53914241; called by muse, mutect2, varscan2
- PDZD2 | c.191C>A p.P64H | Missense Mutation (SNP) | VAF 75/638 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs752516485; called by muse, mutect2, varscan2
- POTEE | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 79/683 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs776851972; called by muse, mutect2, varscan2
- PPM1E | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 107/413 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100375833; called by muse, mutect2, varscan2
- PPP1R2B | c.100A>G p.R34G | Missense Mutation (SNP) | VAF 89/576 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV70372649; called by muse, mutect2, varscan2
- RBMXL2 | c.550G>T p.V184L | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV60978849; called by muse, mutect2, varscan2
- SCG2 | c.1289G>T p.G430V | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV100544755; called by muse, mutect2
- SEMA4D | c.556C>G p.P186A | Missense Mutation (SNP) | VAF 32/256 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as COSV59395635; called by muse, mutect2, varscan2
- SETD1A | c.4469A>T p.Q1490L | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.026); catalogued as COSV52679716; called by muse, mutect2, varscan2
- SH2D4B | c.754C>T p.L252F | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as rs967276225; called by muse, mutect2
- SLC35G1 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.027); catalogued as rs1362991563; called by muse, mutect2
- STK11 | c.876C>A p.Y292* | Nonsense Mutation (SNP) | VAF 43/268 reads (16%) | catalogued as CM108292, CM163276; called by muse, mutect2, varscan2
- SUPT20HL2 | c.65G>T p.R22I | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.171); catalogued as rs373009818; called by muse, mutect2, varscan2
- TG | c.3121C>A p.Q1041K | Missense Mutation (SNP) | VAF 72/582 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758094581, COSV55073838; called by muse, mutect2, varscan2
- TIMD4 | c.785C>A p.S262* | Nonsense Mutation (SNP) | VAF 14/172 reads (8%) | catalogued as COSV50858984; called by muse, mutect2
- TPTE | c.1378G>T p.D460Y (on ENST00000618007 / NM_199261.4; = p.D442Y on NM_199259.4) | Missense Mutation (SNP) | VAF 28/522 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as rs1393711343; called by muse, mutect2
- TRAF3IP3 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 45/445 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs981440427, COSV50550785, COSV50553080; called by muse, mutect2, varscan2
- TSHZ3 | c.1655C>G p.A552G | Missense Mutation (SNP) | VAF 46/279 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53673264; called by muse, mutect2, varscan2
- USH2A | c.6890C>G p.A2297G | Missense Mutation (SNP) | VAF 95/438 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as COSV56364378; called by muse, mutect2, varscan2
- VCAN | c.7031C>A p.P2344H | Missense Mutation (SNP) | VAF 82/556 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as COSV54105591; called by mutect2, varscan2
- VPS45 | c.864G>T p.K288N | Missense Mutation (SNP) | VAF 15/193 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV64887472; called by muse, mutect2
- VWF | c.7331G>T p.W2444L | Missense Mutation (SNP) | VAF 58/475 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54611210; called by muse, mutect2, varscan2
- XKR4 | c.1331G>T p.S444I | Missense Mutation (SNP) | VAF 42/290 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV59315192; called by muse, mutect2, varscan2
- ZNF397 | c.622C>T p.Q208* | Nonsense Mutation (SNP) | VAF 18/123 reads (15%) | catalogued as rs1449110608; called by muse, mutect2, varscan2
- ZNF426 | c.1298C>T p.S433L | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as rs762443939; called by muse, mutect2, varscan2
- ZNF536 | c.2747G>T p.G916V | Missense Mutation (SNP) | VAF 57/336 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV62833012; called by muse, mutect2, varscan2
- ZSCAN10 | c.1062C>A p.C354* (on ENST00000252463; = p.C409* on NM_032805.3) | Nonsense Mutation (SNP) | VAF 28/233 reads (12%) | catalogued as COSV104384117; called by muse, mutect2, varscan2
- ZSWIM2 | c.1085G>T p.C362F | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54576853; called by muse, mutect2, varscan2
- ABCB5 | c.2396C>A p.A799D (on ENST00000404938 / NM_001163941.2; = p.A354D on NM_178559.6) | Missense Mutation (SNP) | VAF 18/199 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- ABCF2 | c.1331C>T p.T444I | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- ABITRAM | c.349G>C p.G117R | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACTR5 | c.908G>T p.R303L | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- ADAM33 | c.457T>A p.W153R | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ADAMTS5 | c.2759C>A p.S920Y | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, varscan2
- ADAMTS9 | c.883G>T p.V295L | Missense Mutation (SNP) | VAF 51/353 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- ADGRF5 | c.3853A>T p.R1285* | Nonsense Mutation (SNP) | VAF 11/212 reads (5%) | called by muse, mutect2
- AGAP2 | c.1259C>G p.S420* (on ENST00000547588 / NM_001122772.2; = p.S84* on NM_014770.4) | Nonsense Mutation (SNP) | VAF 18/229 reads (8%) | called by muse, mutect2
- ALDH16A1 | c.1917G>T p.Q639H | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.145); called by muse, varscan2
- AMPD1 | c.867-2A>T p.X289_splice | Splice Site (SNP) | VAF 48/399 reads (12%) | called by muse, mutect2, varscan2
- AP3B2 | c.1108C>T p.R370W | Missense Mutation (SNP) | VAF 43/263 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ARID4B | c.3115A>T p.S1039C | Missense Mutation (SNP) | VAF 62/439 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- ARPC3 | c.115A>T p.T39S | Missense Mutation (SNP) | VAF 55/400 reads (14%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASTN2 | c.1655G>T p.S552I (on ENST00000313400 / NM_001365069.1; = p.S501I on NM_014010.5) | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- ATP13A5 | c.2334T>A p.H778Q | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- ATP13A5 | c.2332C>A p.H778N | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ATP8A1 | c.2990G>T p.G997V | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- ATP8B1 | c.843G>A p.W281* | Nonsense Mutation (SNP) | VAF 55/289 reads (19%) | called by muse, mutect2, varscan2
- BASP1 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- BBS9 | c.1085A>T p.D362V | Missense Mutation (SNP) | VAF 48/346 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- BTBD17 | c.1150G>T p.A384S | Missense Mutation (SNP) | VAF 14/177 reads (8%) | SIFT tolerated (0.7); PolyPhen benign (0.069); called by muse, mutect2
- C10orf67 | c.1466C>A p.T489K | Missense Mutation (SNP) | VAF 28/326 reads (9%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.914); called by muse, mutect2
- C16orf96 | c.1852G>T p.G618W | Missense Mutation (SNP) | VAF 33/353 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- C4orf54 | c.3379G>T p.E1127* | Nonsense Mutation (SNP) | VAF 30/367 reads (8%) | called by muse, mutect2
- C5orf46 | c.185A>T p.E62V | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- C6 | c.44T>G p.L15R | Missense Mutation (SNP) | VAF 53/505 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- CACNA1S | c.4660C>T p.Q1554* | Nonsense Mutation (SNP) | VAF 119/576 reads (21%) | called by muse, mutect2, varscan2
- CASKIN2 | c.593A>G p.K198R | Missense Mutation (SNP) | VAF 58/177 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- CCDC88B | c.343T>A p.S115T | Missense Mutation (SNP) | VAF 26/303 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.078); called by muse, mutect2
- CDC25A | c.1472A>T p.H491L | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CENPF | c.3023A>T p.E1008V | Missense Mutation (SNP) | VAF 29/311 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- CHD5 | c.3532G>T p.G1178C | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CLEC16A | c.686G>T p.S229I | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.025); called by muse, mutect2
- CMKLR1 | c.497T>A p.L166Q (on ENST00000312143 / NM_001142344.2; = p.L164Q on NM_004072.3) | Missense Mutation (SNP) | VAF 29/275 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CNTNAP5 | c.155C>A p.T52N | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- CNTNAP5 | c.3493A>T p.M1165L | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL22A1 | c.3482C>A p.P1161Q | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL3A1 | c.2347G>A p.G783S | Missense Mutation (SNP) | VAF 68/475 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL4A2 | c.2254G>T p.D752Y | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- COL9A2 | c.1739del p.G580Afs*168 | Frame Shift Del (DEL) | VAF 26/244 reads (11%) | called by mutect2, pindel, varscan2
- CPA2 | c.914T>A p.L305H | Missense Mutation (SNP) | VAF 38/254 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- CR1 | c.5994C>A p.H1998Q | Missense Mutation (SNP) | VAF 25/260 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.054); called by muse, mutect2
- CRLF2 | c.155C>A p.S52Y | Missense Mutation (SNP) | VAF 20/253 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.605); called by muse, mutect2
- DCLK1 | c.2189C>G p.S730C (on ENST00000360631 / NM_001330072.2; = p.S423C on NM_001195416.2) | Missense Mutation (SNP) | VAF 18/275 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.258); called by muse, mutect2
- DDR2 | c.1887G>T p.M629I | Missense Mutation (SNP) | VAF 120/520 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- DDR2 | c.2380G>A p.D794N | Missense Mutation (SNP) | VAF 69/790 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DDX11 | c.1912G>T p.G638W | Missense Mutation (SNP) | VAF 25/310 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DIP2C | c.1492G>T p.E498* | Nonsense Mutation (SNP) | VAF 20/272 reads (7%) | called by muse, mutect2
- DLGAP2 | c.1351G>T p.D451Y | Missense Mutation (SNP) | VAF 32/303 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- DNAI2 | c.610+2dup p.X204_splice | Splice Site (INS) | VAF 60/280 reads (21%) | called by mutect2, varscan2
- DNAJC9 | c.414G>T p.K138N | Missense Mutation (SNP) | VAF 44/372 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- DOC2A | c.1152C>A p.H384Q | Missense Mutation (SNP) | VAF 28/260 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- DPY19L4 | c.1019G>T p.G340V | Missense Mutation (SNP) | VAF 32/232 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- DSC3 | c.200G>T p.S67I | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- DUSP5 | c.611A>C p.H204P | Missense Mutation (SNP) | VAF 43/382 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- DYSF | c.101G>T p.R34I | Missense Mutation (SNP) | VAF 38/584 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2
- EGR2 | c.131T>C p.L44P | Missense Mutation (SNP) | VAF 29/342 reads (8%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.879); called by muse, mutect2
- ESR1 | c.935C>A p.A312D | Missense Mutation (SNP) | VAF 35/439 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); called by muse, mutect2
- ESYT2 | c.2459G>T p.G820V (on ENST00000613624; = p.G744V on NM_020728.3) | Missense Mutation (SNP) | VAF 13/170 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2
- EVPL | c.1208C>G p.A403G | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- FAM13C | c.841A>T p.K281* | Nonsense Mutation (SNP) | VAF 28/228 reads (12%) | called by muse, mutect2, varscan2
- FANCA | c.1357A>T p.K453* | Nonsense Mutation (SNP) | VAF 36/582 reads (6%) | called by muse, mutect2
- FGD5 | c.1234G>T p.D412Y | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- FGF4 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 45/328 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- FOXC1 | c.442A>C p.K148Q | Missense Mutation (SNP) | VAF 36/563 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GADL1 | c.1299G>T p.M433I | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- GALNT1 | c.1531G>T p.V511L | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLI2 | c.1907T>A p.L636Q (on ENST00000361492 / NM_001374353.1; = p.L653Q on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/362 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); called by muse, mutect2
- GNAI1 | c.208A>G p.K70E | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.336); called by muse, mutect2
- GPATCH2 | c.836G>T p.G279V | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); called by muse, varscan2
- GPCPD1 | c.1544del p.K515Sfs*10 | Frame Shift Del (DEL) | VAF 16/120 reads (13%) | called by mutect2, pindel
- GPR132 | c.1033G>T p.E345* | Nonsense Mutation (SNP) | VAF 41/306 reads (13%) | called by muse, mutect2, varscan2
- GRIK1 | c.170C>A p.A57D | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GRK1 | c.700-1G>T p.X234_splice | Splice Site (SNP) | VAF 14/202 reads (7%) | called by muse, mutect2
- GRM5 | c.95C>A p.P32Q | Missense Mutation (SNP) | VAF 43/383 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- GRM6 | c.124G>T p.G42C | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRM8 | c.603C>A p.Y201* | Nonsense Mutation (SNP) | VAF 35/510 reads (7%) | called by muse, mutect2
- GRPR | c.307del p.A103Lfs*13 | Frame Shift Del (DEL) | VAF 29/122 reads (24%) | called by mutect2, pindel, varscan2
- HAUS5 | c.31G>C p.G11R | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT tolerated (0.98); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- HELZ2 | c.5191G>C p.V1731L (on ENST00000467148 / NM_001037335.2; = p.V1162L on NM_033405.3) | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HSPH1 | c.2504G>T p.G835V | Missense Mutation (SNP) | VAF 18/233 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.033); called by muse, mutect2
- IBTK | c.1388G>C p.R463T | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.011); called by muse, mutect2
- IFT122 | c.2722G>T p.E908* (on ENST00000348417 / NM_052989.3; = p.E849* on NM_018262.4) | Nonsense Mutation (SNP) | VAF 52/674 reads (8%) | called by muse, mutect2
- IGFBP3 | c.231G>T p.E77D | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.676); called by muse, mutect2
- IGHV3OR16-8 | c.279C>G p.N93K | Missense Mutation (SNP) | VAF 49/441 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- IL2RG | c.541C>A p.H181N | Missense Mutation (SNP) | VAF 69/290 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- IPMK | c.806A>G p.N269S | Missense Mutation (SNP) | VAF 31/304 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ITGAX | c.916T>A p.S306T | Missense Mutation (SNP) | VAF 35/276 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- KCNJ6 | c.563G>C p.C188S | Missense Mutation (SNP) | VAF 16/261 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KIF6 | c.640-2A>C p.X214_splice | Splice Site (SNP) | VAF 12/224 reads (5%) | called by muse, mutect2
- KIRREL3 | c.2286G>C p.Q762H | Missense Mutation (SNP) | VAF 19/288 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- KLHL29 | c.164C>A p.P55Q | Missense Mutation (SNP) | VAF 39/242 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRT222 | c.97-2A>T p.X33_splice | Splice Site (SNP) | VAF 27/137 reads (20%) | called by muse, mutect2, varscan2
- KRTAP20-2 | c.146G>A p.G49D | Missense Mutation (SNP) | VAF 39/311 reads (13%) | PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- LIN9 | c.182G>C p.R61P | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LRRC32 | c.822C>A p.N274K | Missense Mutation (SNP) | VAF 68/522 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MADD | c.3004-2A>T p.X1002_splice | Splice Site (SNP) | VAF 28/204 reads (14%) | called by muse, mutect2, varscan2
- MAGEB5 | c.67C>A p.P23T | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- MALRD1 | c.3725G>T p.G1242V | Missense Mutation (SNP) | VAF 34/282 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- MED12L | c.1774G>T p.E592* | Nonsense Mutation (SNP) | VAF 42/252 reads (17%) | called by muse, varscan2
- MEIOB | c.270A>T p.E90D | Missense Mutation (SNP) | VAF 17/225 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); called by muse, mutect2
- MEP1A | c.1163G>T p.W388L | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MFRP | c.186G>T p.W62C (on ENST00000449574; = p.W438C on NM_031433.4) | Missense Mutation (SNP) | VAF 45/348 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- MMP25 | c.461G>A p.G154D | Missense Mutation (SNP) | VAF 8/205 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.007); called by muse, mutect2
- MUC17 | c.5860A>T p.R1954W | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC19 | c.634G>T p.E212* | Nonsense Mutation (SNP) | VAF 24/227 reads (11%) | called by muse, varscan2
- MUC2 | c.1390G>T p.G464C | Missense Mutation (SNP) | VAF 42/393 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.418); called by muse, mutect2
- MUC5AC | c.13447C>T p.P4483S | Missense Mutation (SNP) | VAF 60/750 reads (8%) | SIFT tolerated (1); called by muse, varscan2
- MUC5AC | c.14766C>A p.S4922R | Missense Mutation (SNP) | VAF 30/222 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYOZ2 | c.539C>A p.P180H | Missense Mutation (SNP) | VAF 52/278 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NKX6-3 | c.489C>A p.Y163* | Nonsense Mutation (SNP) | VAF 16/228 reads (7%) | called by muse, mutect2
- NOS1 | c.2788del p.E930Rfs*120 | Frame Shift Del (DEL) | VAF 13/136 reads (10%) | called by mutect2, pindel*
- NPAS4 | c.1147G>T p.V383F | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NRCAM | c.2027C>A p.P676H (on ENST00000379028 / NM_001371124.1; = p.P660H on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/249 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- OBSCN | c.5587C>G p.R1863G | Missense Mutation (SNP) | VAF 36/394 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.855); called by muse, mutect2
- OIT3 | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 21/230 reads (9%) | called by muse, mutect2
- OR10G3 | c.442G>T p.G148* | Nonsense Mutation (SNP) | VAF 23/275 reads (8%) | called by muse, mutect2
- OR10H4 | c.309C>A p.F103L | Missense Mutation (SNP) | VAF 43/350 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- OR13C8 | c.356C>G p.A119G | Missense Mutation (SNP) | VAF 34/265 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- OR2T11 | c.491C>A p.P164H | Missense Mutation (SNP) | VAF 102/446 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- OR51F2 | c.158G>C p.C53S | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR56A1 | c.450C>A p.F150L | Missense Mutation (SNP) | VAF 55/485 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR5K1 | c.386C>A p.P129Q | Missense Mutation (SNP) | VAF 19/362 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR6C65 | c.770G>T p.C257F | Missense Mutation (SNP) | VAF 29/195 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- OTOG | c.244G>T p.G82* | Nonsense Mutation (SNP) | VAF 9/71 reads (13%) | called by muse, mutect2, varscan2
- PADI2 | c.1043G>T p.W348L | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PADI3 | c.1566G>T p.Q522H | Missense Mutation (SNP) | VAF 29/371 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2
- PCDH8 | c.1637G>T p.G546V | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2
- PCDHB3 | c.1340A>T p.N447I | Missense Mutation (SNP) | VAF 87/550 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB6 | c.2069T>C p.V690A | Missense Mutation (SNP) | VAF 84/507 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- PCDHGB2 | c.613C>A p.H205N | Missense Mutation (SNP) | VAF 38/304 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PCNX1 | c.4390T>A p.W1464R | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PCNX1 | c.4391G>T p.W1464L | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- PDE6A | c.2237G>A p.G746D | Missense Mutation (SNP) | VAF 55/416 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDZRN3 | c.2824C>A p.L942M | Missense Mutation (SNP) | VAF 26/251 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PEX5 | c.1521del p.V508Wfs*21 (on ENST00000420616; = p.V500Wfs*21 on NM_000319.5) | Frame Shift Del (DEL) | VAF 94/762 reads (12%) | called by pindel, varscan2
- PITPNM3 | c.821A>T p.D274V | Missense Mutation (SNP) | VAF 48/300 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- PLXNA1 | c.1064C>T p.S355L | Missense Mutation (SNP) | VAF 37/347 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- POMGNT1 | c.1539+4A>T | Splice Region (SNP) | VAF 29/493 reads (6%) | called by muse, mutect2
- PPP1R16B | c.872G>C p.R291T | Missense Mutation (SNP) | VAF 25/238 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- PPP1R3A | c.2469G>A p.M823I | Missense Mutation (SNP) | VAF 44/368 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRAMEF10 | c.393G>C p.K131N | Missense Mutation (SNP) | VAF 41/352 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- PREX1 | c.1335-1G>C p.X445_splice | Splice Site (SNP) | VAF 51/520 reads (10%) | called by muse, mutect2
- PREX2 | c.4429A>T p.N1477Y | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); called by muse, varscan2
- PYGL | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 36/472 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RAB3GAP2 | c.1790G>C p.S597T | Missense Mutation (SNP) | VAF 89/415 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- RAI1 | c.4960G>T p.G1654* | Nonsense Mutation (SNP) | VAF 57/337 reads (17%) | called by muse, mutect2, varscan2
- RCOR3 | c.800A>T p.K267I | Missense Mutation (SNP) | VAF 31/296 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- RNASE13 | c.271A>T p.S91C | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- RPH3A | c.900C>A p.S300R (on ENST00000389385 / NM_001143854.2; = p.S296R on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- RPL10L | c.462G>T p.R154S | Missense Mutation (SNP) | VAF 50/340 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- RSPH4A | c.2140G>A p.D714N | Missense Mutation (SNP) | VAF 26/273 reads (10%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.003); called by muse, mutect2
- RYR2 | c.8263C>A p.P2755T | Missense Mutation (SNP) | VAF 19/234 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- RYR2 | c.8264C>A p.P2755Q | Missense Mutation (SNP) | VAF 19/234 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- RYR2 | c.13736A>T p.H4579L | Missense Mutation (SNP) | VAF 47/203 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SAGE1 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SAGE1 | c.700G>T p.D234Y | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- SAMSN1 | c.1079C>A p.S360Y | Missense Mutation (SNP) | VAF 37/341 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- SAMSN1 | c.823C>A p.P275T (on ENST00000647101; = p.P47T on NM_001256370.1) | Missense Mutation (SNP) | VAF 34/246 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- SCARA5 | c.508C>A p.L170M | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- SETDB1 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 51/530 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SI | c.119-5C>A | Splice Region (SNP) | VAF 37/247 reads (15%) | called by muse, mutect2, varscan2
- SIK3 | c.793C>A p.L265M (on ENST00000445177 / NM_001366686.2; = p.L271M on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/255 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC22A31 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- SLC7A8 | c.56del p.G19Afs*16 | Frame Shift Del (DEL) | VAF 15/168 reads (9%) | called by mutect2, pindel
- SNAP47 | c.1287G>C p.E429D | Missense Mutation (SNP) | VAF 43/413 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- SOGA1 | c.2634G>T p.Q878H | Missense Mutation (SNP) | VAF 45/358 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SORCS3 | c.2732T>G p.V911G | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- SPRR1A | c.143C>A p.P48H | Missense Mutation (SNP) | VAF 92/407 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPTAN1 | c.3758A>G p.N1253S | Missense Mutation (SNP) | VAF 59/420 reads (14%) | SIFT tolerated (0.87); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- STMND1 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 13/227 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.755); called by muse, mutect2
- SYT5 | c.46C>A p.P16T | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.908); called by muse, mutect2
- TAAR8 | c.350C>A p.S117Y | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- TAS2R1 | c.56T>A p.L19H | Missense Mutation (SNP) | VAF 66/155 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- TAS2R19 | c.445A>T p.M149L | Missense Mutation (SNP) | VAF 42/279 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.029); called by muse, varscan2
- TENM3 | c.860C>A p.P287H | Missense Mutation (SNP) | VAF 65/436 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- TG | c.7227A>T p.R2409S | Missense Mutation (SNP) | VAF 63/424 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- TGM6 | c.1150C>A p.L384M | Missense Mutation (SNP) | VAF 87/560 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TMCC2 | c.491G>T p.G164V | Missense Mutation (SNP) | VAF 28/269 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMX1 | c.314+3A>T | Splice Region (SNP) | VAF 38/332 reads (11%) | called by muse, mutect2
- TMX1 | c.314+5G>A | Splice Region (SNP) | VAF 36/330 reads (11%) | called by muse, mutect2
- TNN | c.598C>A p.P200T | Missense Mutation (SNP) | VAF 47/219 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- TRBV2 | c.97C>A p.Q33K | Missense Mutation (SNP) | VAF 37/253 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TRERF1 | c.255G>T p.W85C | Missense Mutation (SNP) | VAF 29/324 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- TRPC5 | c.1723C>A p.L575I | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TSC22D4 | c.251C>A p.P84H | Missense Mutation (SNP) | VAF 35/483 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TSPAN15 | c.742G>T p.G248W | Missense Mutation (SNP) | VAF 32/298 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TSPY2 | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 21/243 reads (9%) | called by muse, varscan2
- TSPYL4 | c.448A>T p.K150* | Nonsense Mutation (SNP) | VAF 20/273 reads (7%) | called by muse, mutect2
- TTN | c.30071C>G p.P10024R (on ENST00000591111; = p.P9097R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/272 reads (14%) | PolyPhen benign (0.262); called by muse, mutect2, varscan2
- TYSND1 | c.295G>C p.E99Q | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- UNC45B | c.1367C>A p.T456N | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.876); called by muse, varscan2
- UNKL | c.1172G>T p.G391V | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- USP35 | c.173G>T p.R58L | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.364); called by muse, mutect2
- VIL1 | c.1318C>T p.H440Y | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- VPS45 | c.865A>T p.N289Y | Missense Mutation (SNP) | VAF 15/196 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); called by muse, mutect2
- VWA5A | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 90/616 reads (15%) | called by muse, mutect2, varscan2
- VWF | c.6445G>T p.E2149* | Nonsense Mutation (SNP) | VAF 66/460 reads (14%) | called by muse, mutect2, varscan2
- WDR64 | c.437T>A p.L146Q | Missense Mutation (SNP) | VAF 45/224 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- WSCD2 | c.1454A>T p.Q485L | Missense Mutation (SNP) | VAF 41/370 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZFYVE27 | c.841G>T p.A281S | Missense Mutation (SNP) | VAF 77/552 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- ZHX2 | c.2507A>T p.Q836L | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, varscan2
- ZNF114 | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.01); called by muse, mutect2
- ZNF287 | c.878G>T p.G293V | Missense Mutation (SNP) | VAF 34/229 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ZNF518A | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 16/258 reads (6%) | called by muse, mutect2
- ZNF732 | c.865T>G p.S289A | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ZNF746 | c.1013G>T p.S338I | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- ZNF84 | c.395dup p.L132Ffs*26 | Frame Shift Ins (INS) | VAF 20/214 reads (9%) | called by pindel, varscan2
- ZNF865 | c.2641T>G p.C881G | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- AARD | c.456G>A p.A152= | Silent (SNP) | VAF 17/116 reads (15%) | catalogued as rs748488380, COSV65599677; called by muse, mutect2, varscan2
- ABCA5 | c.2523A>G p.K841= | Silent (SNP) | VAF 27/149 reads (18%) | called by muse, mutect2, varscan2
- ACAN | c.5637T>A p.S1879= | Silent (SNP) | VAF 82/542 reads (15%) | catalogued as rs1337172491; called by muse, mutect2, varscan2
- ACTR5 | c.1761A>T p.S587= | Silent (SNP) | VAF 27/277 reads (10%) | called by muse, mutect2, varscan2
- AGBL4 | c.1506T>A p.P502= | Silent (SNP) | VAF 47/341 reads (14%) | called by muse, mutect2, varscan2
- ATP13A1 | c.2691G>T p.R897= | Silent (SNP) | VAF 46/247 reads (19%) | called by muse, mutect2, varscan2
- ATP13A2 | c.3459G>T p.R1153= | Silent (SNP) | VAF 62/435 reads (14%) | called by muse, mutect2, varscan2
- C12orf42 | c.960C>A p.T320= | Silent (SNP) | VAF 29/163 reads (18%) | called by muse, mutect2, varscan2
- C4orf54 | c.234G>T p.A78= | Silent (SNP) | VAF 21/148 reads (14%) | called by muse, mutect2, varscan2
- CACNA1E | c.6552A>T p.P2184= (on ENST00000367573 / NM_001205293.3; = p.P2141= on NM_000721.4) | Silent (SNP) | VAF 82/357 reads (23%) | called by muse, mutect2, varscan2
- CACNA1I | c.6609C>A p.P2203= | Silent (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- CACNB4 | c.1185G>T p.L395= | Silent (SNP) | VAF 61/435 reads (14%) | catalogued as COSV99138940; called by muse, mutect2, varscan2
- CALCR | c.1329C>T p.R443= (on ENST00000649521 / NM_001164737.2; = p.R427= on NM_001742.4) | Silent (SNP) | VAF 19/145 reads (13%) | catalogued as rs747610842, COSV64006496; called by muse, mutect2, varscan2
- CIT | c.390G>A p.K130= | Silent (SNP) | VAF 40/215 reads (19%) | catalogued as rs748168004, COSV55878652; called by muse, mutect2, varscan2
- CNGB3 | c.1329T>C p.D443= | Silent (SNP) | VAF 48/458 reads (10%) | catalogued as rs1377735742; called by muse, mutect2, varscan2
- CNRIP1 | c.21C>A p.L7= | Silent (SNP) | VAF 14/107 reads (13%) | called by muse, mutect2, varscan2
- DMBT1 | c.7269A>G p.V2423= (on ENST00000338354 / NM_001377530.1; = p.V1666= on NM_004406.3) | Silent (SNP) | VAF 34/348 reads (10%) | called by muse, mutect2
- DNAH11 | c.9147C>T p.H3049= | Silent (SNP) | VAF 23/156 reads (15%) | called by muse, mutect2, varscan2
- DNAJC5B | c.78G>T p.L26= | Silent (SNP) | VAF 25/303 reads (8%) | called by muse, mutect2
- DYNC1LI1 | c.12G>A p.V4= | Silent (SNP) | VAF 12/140 reads (9%) | called by muse, mutect2
- EGR2 | c.132G>T p.L44= | Silent (SNP) | VAF 30/337 reads (9%) | catalogued as COSV54346595; called by muse, mutect2
- EMILIN3 | c.2079G>A p.V693= | Silent (SNP) | VAF 9/80 reads (11%) | called by muse, mutect2, varscan2
- ERCC6 | c.3723G>A p.E1241= | Silent (SNP) | VAF 38/298 reads (13%) | called by muse, mutect2, varscan2
- FAAH | c.1638G>T p.P546= | Silent (SNP) | VAF 35/637 reads (5%) | catalogued as COSV99680361; called by muse, mutect2
- FGD5 | c.3543C>T p.S1181= | Silent (SNP) | VAF 37/288 reads (13%) | catalogued as rs200619206; called by muse, mutect2, varscan2
- FKBP9 | c.513C>T p.Y171= | Silent (SNP) | VAF 32/222 reads (14%) | catalogued as rs1562566346; called by muse, mutect2, varscan2
- FREM3 | c.4557C>T p.L1519= | Silent (SNP) | VAF 55/333 reads (17%) | called by muse, mutect2, varscan2
- FRMPD3 | c.2254C>A p.R752= | Silent (SNP) | VAF 26/113 reads (23%) | catalogued as COSV99346555, COSV99347309; called by muse, mutect2, varscan2
- FSTL4 | c.231G>T p.V77= | Silent (SNP) | VAF 43/337 reads (13%) | called by muse, mutect2, varscan2
- GAS2 | c.460C>A p.R154= | Silent (SNP) | VAF 27/238 reads (11%) | catalogued as COSV53414263; called by muse, mutect2
- GBP4 | c.1281G>T p.R427= | Silent (SNP) | VAF 22/454 reads (5%) | catalogued as COSV63254265; called by muse, mutect2
- GCNT1 | c.366A>G p.P122= | Silent (SNP) | VAF 23/192 reads (12%) | called by muse, mutect2, varscan2
- GPATCH8 | c.2205C>T p.P735= | Silent (SNP) | VAF 72/275 reads (26%) | called by muse, mutect2, varscan2
- GRID2 | c.2832G>T p.L944= | Silent (SNP) | VAF 24/252 reads (10%) | called by muse, mutect2
- GUCY2C | c.1339C>T p.L447= | Silent (SNP) | VAF 28/238 reads (12%) | called by muse, mutect2, varscan2
- HDC | c.1455T>A p.P485= | Silent (SNP) | VAF 28/193 reads (15%) | called by muse, mutect2, varscan2
- HTR3A | c.153C>T p.P51= | Silent (SNP) | VAF 50/404 reads (12%) | catalogued as rs768843379; called by muse, mutect2, varscan2
- IL18R1 | c.978C>A p.V326= | Silent (SNP) | VAF 26/232 reads (11%) | called by muse, mutect2, varscan2
- IL21R | c.840G>C p.L280= | Silent (SNP) | VAF 20/215 reads (9%) | called by muse, mutect2
- IQCF3 | c.222G>T p.R74= | Silent (SNP) | VAF 16/170 reads (9%) | catalogued as rs753177853; called by muse, mutect2
- KCNH5 | c.2637G>C p.G879= | Silent (SNP) | VAF 20/301 reads (7%) | called by muse, mutect2
- KRTAP10-2 | c.216C>A p.T72= | Silent (SNP) | VAF 68/640 reads (11%) | called by muse, mutect2, varscan2
- LAMA4 | c.915C>A p.A305= (on ENST00000230538 / NM_001105206.3; = p.A298= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/543 reads (7%) | called by muse, mutect2
- LHX9 | c.423C>A p.S141= | Silent (SNP) | VAF 36/170 reads (21%) | catalogued as COSV61331956, COSV61332133; called by muse, mutect2, varscan2
- LRP11 | c.498G>C p.T166= | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as rs1230419580, COSV53335377; called by muse, mutect2
- LRRC4B | c.1473C>T p.T491= | Silent (SNP) | VAF 15/258 reads (6%) | catalogued as rs1288477889; called by muse, mutect2
- MAGI1 | c.147G>C p.A49= | Silent (SNP) | VAF 45/362 reads (12%) | called by muse, mutect2, varscan2
- MAPK3 | c.78G>T p.G26= | Silent (SNP) | VAF 14/110 reads (13%) | catalogued as rs573393991; called by muse, mutect2, varscan2
- MCRS1 | c.753G>T p.L251= | Silent (SNP) | VAF 23/189 reads (12%) | called by muse, mutect2, varscan2
- MET | c.2151A>T p.S717= | Silent (SNP) | VAF 35/325 reads (11%) | called by muse, mutect2, varscan2
- MMRN1 | c.249G>T p.L83= | Silent (SNP) | VAF 43/339 reads (13%) | catalogued as COSV53336451; called by muse, mutect2, varscan2
- MROH8 | c.1143G>T p.L381= | Silent (SNP) | VAF 23/167 reads (14%) | called by muse, mutect2, varscan2
- MRPS9 | c.1032A>C p.I344= | Silent (SNP) | VAF 7/121 reads (6%) | catalogued as COSV51519562; called by muse, mutect2
- MYRF | c.1089C>A p.T363= (on ENST00000278836 / NM_001127392.3; = p.T354= on NM_013279.4) | Silent (SNP) | VAF 26/208 reads (13%) | called by muse, mutect2, varscan2
- N4BP1 | c.15G>T p.A5= | Silent (SNP) | VAF 9/71 reads (13%) | called by muse, mutect2, varscan2
- NOS1 | c.3045G>T p.R1015= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as rs1414751252; called by muse, varscan2
- NPAS4 | c.237G>T p.A79= | Silent (SNP) | VAF 30/297 reads (10%) | catalogued as rs1405001077; called by muse, mutect2, varscan2
- NRCAM | c.2028C>A p.P676= (on ENST00000379028 / NM_001371124.1; = p.P660= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 25/247 reads (10%) | called by muse, mutect2
- NT5DC4 | c.189C>A p.P63= | Silent (SNP) | VAF 26/354 reads (7%) | called by muse, mutect2
- NTN3 | c.895C>A p.R299= | Silent (SNP) | VAF 17/117 reads (15%) | catalogued as COSV104396261; called by muse, mutect2, varscan2
- OR10A4 | c.57C>T p.A19= | Silent (SNP) | VAF 19/168 reads (11%) | catalogued as COSV65842004; called by muse, mutect2, varscan2
- OR2G2 | c.705C>T p.T235= | Silent (SNP) | VAF 31/373 reads (8%) | catalogued as COSV60740908; called by muse, mutect2
- OR2M2 | c.849C>T p.P283= | Silent (SNP) | VAF 32/520 reads (6%) | catalogued as COSV62898787, COSV62899319; called by muse, mutect2
- OR2T27 | c.483C>G p.P161= | Silent (SNP) | VAF 28/481 reads (6%) | called by muse, mutect2
- OR8K1 | c.312C>G p.A104= | Silent (SNP) | VAF 37/342 reads (11%) | called by muse, mutect2, varscan2
- OR8S1 | c.676C>T p.L226= | Silent (SNP) | VAF 58/476 reads (12%) | called by muse, mutect2, varscan2
- PCDHB9 | c.1381C>A p.R461= | Silent (SNP) | VAF 101/713 reads (14%) | called by muse, mutect2, varscan2
- PHF21B | c.1308A>T p.R436= | Silent (SNP) | VAF 12/152 reads (8%) | called by muse, mutect2
- PHF7 | c.108C>T p.C36= | Silent (SNP) | VAF 18/213 reads (8%) | called by muse, mutect2
- PLIN1 | c.691C>A p.R231= | Silent (SNP) | VAF 60/407 reads (15%) | catalogued as COSV55584240; called by muse, mutect2, varscan2
- PLPP4 | c.486G>T p.A162= | Silent (SNP) | VAF 22/138 reads (16%) | called by muse, mutect2, varscan2
- POC1B | c.117T>C p.D39= | Silent (SNP) | VAF 15/128 reads (12%) | catalogued as COSV57962760; called by muse, mutect2, varscan2
- PRDM8 | c.513G>A p.V171= | Silent (SNP) | VAF 53/474 reads (11%) | called by muse, mutect2, varscan2
- PRKCG | c.1425C>T p.G475= | Silent (SNP) | VAF 149/898 reads (17%) | catalogued as rs756913177; called by muse, mutect2, varscan2
- PTK2 | c.828A>G p.P276= | Silent (SNP) | VAF 33/350 reads (9%) | catalogued as COSV61783737, COSV61784597; called by muse, mutect2
- RESP18 | c.207G>T p.G69= | Silent (SNP) | VAF 18/144 reads (13%) | called by muse, mutect2, varscan2
- RIPPLY2 | c.375C>A p.T125= | Silent (SNP) | VAF 13/184 reads (7%) | called by muse, mutect2
- ROBO2 | c.240C>A p.S80= | Silent (SNP) | VAF 47/368 reads (13%) | called by muse, mutect2, varscan2
- RPS6KA6 | c.1176A>C p.A392= | Silent (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2
- SEMA6A | c.2541C>A p.A847= | Silent (SNP) | VAF 54/425 reads (13%) | called by muse, mutect2, varscan2
- SETBP1 | c.2752C>A p.R918= | Silent (SNP) | VAF 54/360 reads (15%) | catalogued as COSV56313515; called by muse, mutect2, varscan2
- SHISA6 | c.591C>A p.V197= | Silent (SNP) | VAF 99/637 reads (16%) | called by muse, mutect2, varscan2
- SLC11A1 | c.820C>A p.R274= | Silent (SNP) | VAF 20/141 reads (14%) | called by muse, mutect2, varscan2
- SLC12A5 | c.2851C>A p.R951= (on ENST00000454036 / NM_001134771.2; = p.R928= on NM_020708.5) | Silent (SNP) | VAF 20/168 reads (12%) | called by muse, mutect2, varscan2
- SLC6A5 | c.2313G>A p.K771= | Silent (SNP) | VAF 73/534 reads (14%) | called by muse, mutect2, varscan2
- SLC7A14 | c.1368G>T p.L456= | Silent (SNP) | VAF 70/484 reads (14%) | called by muse, mutect2, varscan2
- SORCS1 | c.351G>A p.K117= | Silent (SNP) | VAF 36/372 reads (10%) | called by muse, mutect2
- SORL1 | c.3573C>T p.N1191= | Silent (SNP) | VAF 16/82 reads (20%) | called by muse, mutect2, varscan2
- SPRR1A | c.144C>A p.P48= | Silent (SNP) | VAF 94/403 reads (23%) | catalogued as COSV61081661; called by muse, mutect2, varscan2
- ST18 | c.1479A>G p.E493= | Silent (SNP) | VAF 25/282 reads (9%) | catalogued as rs781324136; called by muse, mutect2
- TBL2 | c.840G>T p.A280= | Silent (SNP) | VAF 35/282 reads (12%) | catalogued as rs190733739; called by muse, mutect2, varscan2
- TPST1 | c.303C>T p.T101= | Silent (SNP) | VAF 39/250 reads (16%) | called by muse, mutect2, varscan2
- TSKS | c.1239G>T p.G413= | Silent (SNP) | VAF 30/178 reads (17%) | called by muse, mutect2, varscan2
- UGT3A1 | c.1233G>T p.R411= | Silent (SNP) | VAF 135/549 reads (25%) | called by muse, mutect2, varscan2
- USH1G | c.805C>A p.R269= | Silent (SNP) | VAF 75/280 reads (27%) | catalogued as CM1411370; called by muse, mutect2, varscan2
- USH1G | c.804C>A p.G268= | Silent (SNP) | VAF 74/282 reads (26%) | called by muse, mutect2, varscan2
- VSIG10L | c.603G>T p.V201= | Silent (SNP) | VAF 16/107 reads (15%) | called by muse, mutect2, varscan2
- VSIG8 | c.1119G>T p.L373= | Silent (SNP) | VAF 11/154 reads (7%) | called by muse, mutect2
- WNK3 | c.4002G>A p.R1334= | Silent (SNP) | VAF 17/76 reads (22%) | called by muse, mutect2, varscan2
- ZNF25 | c.402A>T p.I134= | Silent (SNP) | VAF 36/255 reads (14%) | catalogued as COSV100224697; called by muse, mutect2, varscan2
- ZNF524 | c.558G>T p.A186= | Silent (SNP) | VAF 37/242 reads (15%) | catalogued as COSV99684558; called by muse, mutect2, varscan2
- ZNF804B | c.3930G>A p.L1310= | Silent (SNP) | VAF 41/315 reads (13%) | called by muse, mutect2, varscan2
- A1BG | c.*90C>A | 3'UTR (SNP) | VAF 54/312 reads (17%) | called by muse, mutect2, varscan2
- AC244394.2 | n.1521C>A | RNA (SNP) | VAF 15/232 reads (6%) | catalogued as rs1553896067; called by muse, mutect2
- AGPAT4 | c.348+551T>C | Intron (SNP) | VAF 12/188 reads (6%) | called by muse, mutect2
- AL133467.6 | chr14:95668262 C>T | 5'Flank (SNP) | VAF 39/424 reads (9%) | called by muse, mutect2
- AP1S3 | c.*31A>G | 3'UTR (SNP) | VAF 8/38 reads (21%) | catalogued as rs951216025; called by muse, varscan2
- ARHGEF1 | c.1121+13G>T | Intron (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2, varscan2
- ATP4A | c.2326+9C>A | Intron (SNP) | VAF 55/279 reads (20%) | called by mutect2, varscan2
- BLK | c.953-26G>A | Intron (SNP) | VAF 47/372 reads (13%) | called by muse, mutect2, varscan2
- CACNA2D4 | c.1645-48C>A | Intron (SNP) | VAF 49/414 reads (12%) | called by muse, mutect2, varscan2
- CTNNBL1 | c.-74_-73insCT | 5'UTR (INS) | VAF 16/136 reads (12%) | called by mutect2, varscan2*
- CTNNBL1 | c.-72_-71del | 5'UTR (DEL) | VAF 18/147 reads (12%) | called by mutect2, varscan2*
- CYP26C1 | c.-26A>G | 5'UTR (SNP) | VAF 24/198 reads (12%) | called by muse, mutect2, varscan2
- DIRC1 | n.443C>A | RNA (SNP) | VAF 56/348 reads (16%) | catalogued as COSV57365820; called by muse, mutect2, varscan2
- DNM1P46 | chr15:99808276 G>T | 5'Flank (SNP) | VAF 20/175 reads (11%) | called by muse, mutect2, varscan2
- EPN1 | c.-101-1353G>T | Intron (SNP) | VAF 20/172 reads (12%) | called by muse, mutect2, varscan2
- FHOD3 | c.1197-5376C>G | Intron (SNP) | VAF 42/308 reads (14%) | called by muse, mutect2, varscan2
- FUT7 | chr9:137034719 C>A | 5'Flank (SNP) | VAF 37/279 reads (13%) | called by muse, mutect2, varscan2
- GRIK4 | c.907-2315G>T | Intron (SNP) | VAF 34/400 reads (9%) | catalogued as rs993578393; called by muse, mutect2
- GRM8 | c.727+30315A>T | Intron (SNP) | VAF 22/175 reads (13%) | called by muse, mutect2, varscan2
- GVINP1 | n.4390G>T | RNA (SNP) | VAF 34/316 reads (11%) | catalogued as rs1564888071; called by muse, mutect2, varscan2
- HNRNPA3P1 | n.62G>A | RNA (SNP) | VAF 29/232 reads (13%) | called by muse, mutect2, varscan2
- HSP90AB3P | n.1075G>A | RNA (SNP) | VAF 50/388 reads (13%) | catalogued as rs181331782; called by muse, mutect2, varscan2
- KCNAB1 | chr3:156118304 C>A | 5'Flank (SNP) | VAF 17/151 reads (11%) | called by muse, mutect2, varscan2
- KIF21B | chr1:200973446 C>A | 3'Flank (SNP) | VAF 5/54 reads (9%) | catalogued as COSV100144389; called by muse, mutect2
- KLHDC1 | c.484-22A>G | Intron (SNP) | VAF 11/102 reads (11%) | catalogued as rs757365511; called by muse, mutect2, varscan2
- LINC01148 | n.491A>T | RNA (SNP) | VAF 11/70 reads (16%) | called by muse, mutect2, varscan2
- LINC01548 | n.442T>A | RNA (SNP) | VAF 32/257 reads (12%) | called by muse, mutect2, varscan2
- LTBP4 | chr19:40593094 G>T | 5'Flank (SNP) | VAF 29/196 reads (15%) | called by muse, mutect2, varscan2
- MASP1 | c.1303+5248C>A | Intron (SNP) | VAF 37/514 reads (7%) | called by muse, mutect2
- MCF2L | c.3278+33G>T | Intron (SNP) | VAF 17/207 reads (8%) | catalogued as COSV99995787; called by muse, mutect2
- MIR4739 | chr17:79707342 G>T | 5'Flank (SNP) | VAF 67/222 reads (30%) | called by muse, mutect2, varscan2
- MIR6859-3 | chr15:101975075 A>T | 3'Flank (SNP) | VAF 36/659 reads (5%) | called by muse, mutect2
- MSC-AS1 | n.422C>A | RNA (SNP) | VAF 56/479 reads (12%) | called by muse, mutect2, varscan2
- MYO3A | c.*18C>A | 3'UTR (SNP) | VAF 15/102 reads (15%) | called by muse, varscan2
- NDUFV1 | chr11:67604940 T>C | 5'Flank (SNP) | VAF 40/294 reads (14%) | called by muse, mutect2, varscan2
- NRBP2 | c.1317+41C>T | Intron (SNP) | VAF 6/127 reads (5%) | catalogued as rs782149448; called by muse, mutect2
- OR52B1P | n.340C>T | RNA (SNP) | VAF 49/403 reads (12%) | called by muse, mutect2, varscan2
- OR52B1P | n.242C>A | RNA (SNP) | VAF 56/343 reads (16%) | catalogued as rs773415960; called by muse, mutect2, varscan2
- PIPSL | n.1564C>A | RNA (SNP) | VAF 57/512 reads (11%) | called by muse, mutect2, varscan2
- PLEKHM1 | c.*359A>C | 3'UTR (SNP) | VAF 52/638 reads (8%) | called by muse, mutect2
- RNU6-1224P | chr8:102529379 G>T | 3'Flank (SNP) | VAF 14/135 reads (10%) | catalogued as rs1168477221; called by muse, mutect2, varscan2
- RPS3A | c.355-779T>A | Intron (SNP) | VAF 10/162 reads (6%) | called by muse, mutect2
- SLC25A13 | c.-116G>T | 5'UTR (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2, varscan2
- SLC9A3R2 | c.415-3013C>T | Intron (SNP) | VAF 26/237 reads (11%) | called by muse, mutect2, varscan2
- TCAP | c.*42G>T | 3'UTR (SNP) | VAF 59/187 reads (32%) | called by muse, mutect2, varscan2
- TGM2 | c.*26G>T | 3'UTR (SNP) | VAF 20/190 reads (11%) | called by muse, mutect2
- TOP1 | c.-84C>T | 5'UTR (SNP) | VAF 13/117 reads (11%) | catalogued as rs1271627905; called by muse, mutect2, varscan2
- VAMP7 | c.*141C>G | 3'UTR (SNP) | VAF 24/306 reads (8%) | called by muse, mutect2
- ZNF302 | c.10-26G>C | Intron (SNP) | VAF 30/189 reads (16%) | called by muse, mutect2, varscan2
